Somatic mutation profile of tumor specimen TCGA-HM-A6W2-06A (aliquot TCGA-HM-A6W2-06A-22D-A33O-09) from TCGA case TCGA-HM-A6W2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.0 years (12,775 days).
Specimen TCGA-HM-A6W2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f27d522e-4961-41b8-93bf-a3f88599018e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HM-A6W2-10A (Blood Derived Normal), aliquot TCGA-HM-A6W2-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee3456b-23e0-4666-90f2-40e9e6d8188d

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TACR3 | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as rs760022956, CS104228, COSV59199949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 39/42 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs755344743, COSV101275975; called by muse, mutect2, varscan2
- ABCC9 | c.3238C>A p.P1080T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99685909; called by muse, mutect2, varscan2
- ATP13A4 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61326811; called by muse, mutect2, varscan2
- ATRIP | c.342A>T p.L114F | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.046); catalogued as COSV100202783; called by muse, varscan2
- BCAN | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100228171; called by muse, mutect2, varscan2
- CAPZA3 | c.110T>A p.L37H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856460; called by muse, mutect2, varscan2
- DGKK | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV101053035; called by muse, mutect2, varscan2
- EEA1 | c.1200_1202del p.Q401del | In Frame Del (DEL) | VAF 31/96 reads (32%) | catalogued as rs766291127; called by pindel, varscan2
- FAM153A | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100647054; called by muse, mutect2, varscan2
- FAM153B | c.637G>T p.E213* (on ENST00000253490; = p.E136* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99498953; called by muse, mutect2, varscan2
- FBF1 | c.2567C>T p.A856V (on ENST00000586717; = p.A870V on NM_001319193.1) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs1423532137, COSV100045236; called by muse, mutect2, varscan2
- FSCB | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs762771265, COSV61217485; called by muse, mutect2, varscan2
- GJB4 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.394); catalogued as rs185327282; called by muse, mutect2, varscan2
- GNAL | c.547-2A>T p.X183_splice (on ENST00000269162 / NM_001142339.3; = p.X260_splice on NM_182978.4) | Splice Site (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99303666; called by muse, mutect2, varscan2
- GSPT2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV100468204; called by muse, mutect2, varscan2
- HSPA12A | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs781929997, COSV65023664; called by muse, mutect2, varscan2
- IL1RAP | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs770012788, COSV50760435; called by muse, mutect2, varscan2
- KAT6B | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs761295315, COSV99768280; called by muse, mutect2, varscan2
- MAP3K21 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759521299, COSV100786190; called by muse, mutect2
- MME | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs200787530, COSV64707572; called by muse, mutect2, varscan2
- NDUFS1 | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99261041; called by muse, mutect2, varscan2
- PCDHA13 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV56487670; called by muse, mutect2, varscan2
- PLOD3 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.041); catalogued as rs376302927; called by muse, mutect2, varscan2
- PNLDC1 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99277503; called by muse, mutect2, varscan2
- RTEL1 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100542412; called by muse, mutect2, varscan2
- SF3B4 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99641210; called by muse, mutect2, varscan2
- SH2B1 | c.1692C>G p.Y564* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV100451093; called by muse, mutect2, varscan2
- SS18L1 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59212788; called by muse, mutect2, varscan2
- SYCP1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101050980, COSV65696175; called by muse, mutect2, varscan2
- UBR4 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV100921043; called by muse, mutect2, varscan2
- PDE3A | c.511del p.E171Kfs*36 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | called by mutect2, pindel, varscan2
- TYRO3 | c.1183_1184del p.C395Rfs*20 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by pindel, varscan2
- COL11A1 | c.879G>A p.E293= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs749538662, COSV100616929; called by muse, mutect2, varscan2
- CYLC1 | c.1689C>T p.G563= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV100254785; called by muse, mutect2, varscan2
- DCAF5 | c.1221G>A p.Q407= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1024584172, COSV100432566; called by muse, mutect2, varscan2
- HSF1 | c.714C>T p.G238= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100184056; called by muse, mutect2, varscan2
- HSPBP1 | c.873C>T p.H291= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs1013095423, COSV99729101; called by muse, mutect2, varscan2
- MACF1 | c.20784T>C p.T6928= (on ENST00000372915; = p.T4973= on NM_012090.5) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99244908; called by muse, mutect2, varscan2
- MIB2 | c.1632C>T p.D544= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV100598940; called by muse, mutect2, varscan2
- MNAT1 | c.61C>T p.L21= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs141089655, COSV99710400; called by muse, mutect2, varscan2
- PODN | c.1779G>A p.T593= (on ENST00000395871; = p.T545= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs547822345, COSV57011524; called by muse, mutect2, varscan2
- SLIT2 | c.954A>T p.G318= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99884446; called by muse, mutect2, varscan2
- TGM7 | c.90C>T p.V30= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV101476871; called by muse, mutect2, varscan2
- TUBA1C | c.984C>T p.V328= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99988823; called by muse, mutect2, varscan2
- VPS13D | c.12957G>A p.V4319= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV50632110; called by muse, mutect2, varscan2
- TTN | c.34264+5521G>T | Intron (SNP) | VAF 32/65 reads (49%) | catalogued as COSV100616651, COSV60293460; called by muse, mutect2, varscan2
